Somatic mutation profile of tumor specimen TCGA-FD-A3SR-01A (aliquot TCGA-FD-A3SR-01A-11D-A22Z-08) from TCGA case TCGA-FD-A3SR, project TCGA-BLCA (Bladder Urothelial Carcinoma). Sex at birth: male; Vital status: Dead; Primary diagnosis: Transitional cell carcinoma; Tissue or organ of origin: Posterior wall of bladder; AJCC pathologic stage: Stage IV; Tumor grade: High Grade; Age at diagnosis: 68.4 years (24,979 days).
Specimen TCGA-FD-A3SR-01A: Sample type: Primary Tumor; Tissue type: Tumor; Tumor descriptor: Primary; Specimen type: Solid Tissue; Preservation method: OCT.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) a6817635-66d0-4505-ac55-e358234c7085.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen TCGA-FD-A3SR-10A (Blood Derived Normal), aliquot TCGA-FD-A3SR-10A-01D-A22Z-08; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/09f4e79a-6462-457e-bab3-47925b52a452

The open-access MAF lists 151 somatic variants for this specimen: 126 protein-altering or splice-affecting, 23 silent, 2 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 109, Silent 23, Nonsense Mutation 11, Frame Shift Del 3, 5'UTR 1, Splice Site 1, Splice Region 1, Intron 1, Frame Shift Ins 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- TP53 | c.476C>T p.A159V | Missense Mutation (SNP) | VAF 18/86 reads (21%) | hotspot (GDC flag); SIFT deleterious (0); PolyPhen possibly damaging (0.772); catalogued as rs1555526131, COSV52674926, COSV52693942, COSV52759722; ClinVar: uncertain significance; called by muse, mutect2, varscan2
- ABHD16B | c.743T>C p.V248A | Missense Mutation (SNP) | VAF 8/28 reads (29%) | SIFT deleterious (0); PolyPhen benign (0.065); catalogued as COSV53863643; called by muse, mutect2, varscan2
- ADGRD1 | c.1942G>A p.A648T | Missense Mutation (SNP) | VAF 34/189 reads (18%) | SIFT tolerated (0.06); PolyPhen benign (0.149); catalogued as rs756810149, COSV55442677; called by muse, mutect2, varscan2
- ADRA1A | c.931G>A p.V311I | Missense Mutation (SNP) | VAF 19/82 reads (23%) | SIFT tolerated (1); PolyPhen benign (0.001); catalogued as rs267601877, CM057864, COSV52365871; called by mutect2, varscan2
- AJM1 | c.1022C>T p.S341F | Missense Mutation (SNP) | VAF 5/23 reads (22%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs1164640387, COSV56034304; called by muse, mutect2, varscan2
- ARID1A | c.1813C>G p.Q605E | Missense Mutation (SNP) | VAF 12/87 reads (14%) | SIFT deleterious (0); PolyPhen probably damaging (0.93); catalogued as COSV61377198, COSV61384452, COSV61387404; called by muse, mutect2, varscan2
- ARID2 | c.1913-1G>A p.X638_splice | Splice Site (SNP) | VAF 34/89 reads (38%) | catalogued as COSV57610763; called by muse, mutect2, varscan2
- ASXL3 | c.6421A>G p.K2141E | Missense Mutation (SNP) | VAF 35/121 reads (29%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.994); catalogued as COSV52473995; called by muse, mutect2, varscan2
- BRD4 | c.1663G>T p.E555* | Nonsense Mutation (SNP) | VAF 7/48 reads (15%) | catalogued as COSV99651434; called by muse, mutect2, varscan2
- BRPF3 | c.56C>T p.S19F | Missense Mutation (SNP) | VAF 6/84 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as COSV60206277, COSV60208851; called by muse, mutect2
- C1orf94 | c.691G>A p.D231N (on ENST00000488417 / NM_001134734.2; = p.D41N on NM_032884.5) | Missense Mutation (SNP) | VAF 14/49 reads (29%) | SIFT tolerated (0.22); PolyPhen benign (0.12); catalogued as COSV64914850; called by muse, mutect2, varscan2
- CDH18 | c.1096G>C p.D366H | Missense Mutation (SNP) | VAF 19/76 reads (25%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.999); catalogued as COSV56941936, COSV56945428; called by muse, mutect2, varscan2
- CEP164 | c.3184C>T p.H1062Y | Missense Mutation (SNP) | VAF 31/153 reads (20%) | SIFT deleterious (0.02); PolyPhen benign (0.007); catalogued as COSV54044367; called by muse, mutect2, varscan2
- CEP170 | c.2939C>T p.S980L | Missense Mutation (SNP) | VAF 33/81 reads (41%) | SIFT deleterious (0.04); PolyPhen probably damaging (0.977); catalogued as COSV100317907; called by muse, mutect2, varscan2
- CHD3 | c.4155G>C p.K1385N | Missense Mutation (SNP) | VAF 6/23 reads (26%) | SIFT deleterious (0); PolyPhen benign (0.243); catalogued as COSV57878318; called by muse, mutect2, varscan2
- COL7A1 | c.3419C>G p.T1140R | Missense Mutation (SNP) | VAF 70/168 reads (42%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.522); catalogued as COSV60399842; called by muse, mutect2, varscan2
- CWC27 | c.802G>C p.E268Q | Missense Mutation (SNP) | VAF 17/51 reads (33%) | SIFT tolerated (0.3); PolyPhen benign (0.009); catalogued as COSV66887523; called by muse, mutect2, varscan2
- CXorf66 | c.538G>A p.E180K | Missense Mutation (SNP) | VAF 69/223 reads (31%) | SIFT tolerated (0.26); PolyPhen benign (0.319); catalogued as COSV65169588; called by muse, mutect2, varscan2
- DCP2 | c.235C>G p.Q79E | Missense Mutation (SNP) | VAF 23/111 reads (21%) | SIFT tolerated (0.09); PolyPhen benign (0.003); catalogued as rs1486135967, COSV66617848; called by muse, mutect2, varscan2
- DPP6 | c.1485G>C p.E495D (on ENST00000377770 / NM_001364500.2; = p.E433D on NM_001936.5) | Missense Mutation (SNP) | VAF 4/17 reads (24%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.45); catalogued as COSV59633491; called by muse, mutect2
- DST | c.17086G>A p.D5696N (on ENST00000361203 / NM_001374722.1; = p.D3393N on NM_015548.5) | Missense Mutation (SNP) | VAF 36/165 reads (22%) | SIFT tolerated (0.08); PolyPhen benign (0.1); catalogued as COSV55030305; called by muse, mutect2, varscan2
- DST | c.14416C>A p.L4806M (on ENST00000361203 / NM_001374722.1; = p.L2394M on NM_015548.5) | Missense Mutation (SNP) | VAF 36/108 reads (33%) | SIFT tolerated (0.07); PolyPhen possibly damaging (0.537); catalogued as COSV55030321; called by muse, mutect2, varscan2
- EIF4A3 | c.460G>C p.D154H | Missense Mutation (SNP) | VAF 5/65 reads (8%) | SIFT deleterious (0.02); PolyPhen benign (0.031); catalogued as COSV53921702; called by muse, mutect2
- EIF4A3 | c.260G>A p.G87E | Missense Mutation (SNP) | VAF 4/93 reads (4%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV99484219; called by muse, mutect2
- EMILIN2 | c.2249C>T p.S750L | Missense Mutation (SNP) | VAF 20/187 reads (11%) | SIFT tolerated (0.09); PolyPhen benign (0.154); catalogued as rs769265069, COSV54425977; called by muse, mutect2, varscan2
- EPS8 | c.1139C>A p.S380* | Nonsense Mutation (SNP) | VAF 15/88 reads (17%) | catalogued as COSV104385202; called by muse, mutect2, varscan2
- ERP29 | c.17C>T p.P6L | Missense Mutation (SNP) | VAF 15/84 reads (18%) | SIFT deleterious, low confidence (0.01); PolyPhen benign (0); catalogued as rs772553444, COSV55673895; called by muse, mutect2, varscan2
- ESRRA | c.679A>G p.T227A | Missense Mutation (SNP) | VAF 13/35 reads (37%) | SIFT tolerated (0.16); PolyPhen possibly damaging (0.893); catalogued as COSV50007432; called by muse, mutect2, varscan2
- EVC2 | c.3377C>T p.S1126L | Missense Mutation (SNP) | VAF 7/19 reads (37%) | SIFT deleterious (0.03); PolyPhen benign (0.06); catalogued as rs201735294; called by muse, mutect2, varscan2
- F2RL1 | c.179C>G p.S60C | Missense Mutation (SNP) | VAF 34/110 reads (31%) | SIFT deleterious (0.02); PolyPhen benign (0.028); catalogued as COSV56996424, COSV56996764; called by muse, mutect2, varscan2
- FAM160A2 | c.1076G>A p.R359Q | Missense Mutation (SNP) | VAF 21/57 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as COSV56413399; called by muse, mutect2, varscan2
- FMO3 | c.1537C>T p.H513Y | Missense Mutation (SNP) | VAF 66/117 reads (56%) | SIFT tolerated (1); PolyPhen benign (0.003); catalogued as COSV100882530, COSV63006734; called by muse, mutect2, varscan2
- FZD3 | c.394G>A p.D132N | Missense Mutation (SNP) | VAF 32/118 reads (27%) | SIFT tolerated (0.33); PolyPhen benign (0.021); catalogued as COSV53536958; called by muse, mutect2, varscan2
- GALNT15 | c.1865G>T p.G622V | Missense Mutation (SNP) | VAF 23/54 reads (43%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.551); catalogued as COSV60218606; called by muse, mutect2, varscan2
- GALNTL6 | c.1730C>T p.S577F | Missense Mutation (SNP) | VAF 16/91 reads (18%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.994); catalogued as rs1414736847, COSV72492419; called by muse, mutect2, varscan2
- GHR | c.1018G>A p.D340N | Missense Mutation (SNP) | VAF 133/285 reads (47%) | SIFT deleterious (0.02); PolyPhen probably damaging (1); catalogued as COSV50122244; called by muse, mutect2, varscan2
- GIMAP8 | c.1192G>A p.A398T | Missense Mutation (SNP) | VAF 25/143 reads (17%) | SIFT tolerated (0.2); PolyPhen benign (0.001); catalogued as COSV56232964; called by muse, mutect2, varscan2
- GLI2 | c.4033G>A p.A1345T (on ENST00000361492 / NM_001374353.1; = p.A1362T on NM_005270.5 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 4/12 reads (33%) | SIFT tolerated (0.17); PolyPhen benign (0.003); catalogued as COSV58047656; called by muse, mutect2, varscan2
- GNAI3 | c.712G>A p.E238K | Missense Mutation (SNP) | VAF 43/166 reads (26%) | SIFT tolerated (0.1); PolyPhen benign (0.215); catalogued as rs1398180623, COSV63983695; called by muse, mutect2, varscan2
- HACL1 | c.745A>G p.M249V | Missense Mutation (SNP) | VAF 37/91 reads (41%) | SIFT deleterious (0); PolyPhen probably damaging (0.994); catalogued as rs376301747; called by muse, mutect2, varscan2
- HHIP | c.322G>C p.E108Q | Missense Mutation (SNP) | VAF 20/119 reads (17%) | SIFT tolerated (0.28); PolyPhen benign (0.018); catalogued as COSV56842435, COSV99666400; called by muse, mutect2, varscan2
- HHIP | c.1427G>A p.S476N | Missense Mutation (SNP) | VAF 10/44 reads (23%) | SIFT tolerated (0.66); PolyPhen benign (0); catalogued as rs147064425; called by mutect2, varscan2
- HOXC8 | c.631G>A p.D211N | Missense Mutation (SNP) | VAF 17/68 reads (25%) | SIFT deleterious (0); PolyPhen possibly damaging (0.728); catalogued as COSV50000589, COSV50002386; called by muse, mutect2, varscan2
- HSP90AA1 | c.1048G>C p.D350H | Missense Mutation (SNP) | VAF 14/76 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV53488270, COSV53490404; called by muse, mutect2, varscan2
- HYAL2 | c.428G>A p.R143H | Missense Mutation (SNP) | VAF 24/123 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV51700978; called by muse, mutect2, varscan2
- HYDIN | c.115G>T p.E39* | Nonsense Mutation (SNP) | VAF 12/82 reads (15%) | catalogued as COSV55489146; called by muse, mutect2, varscan2
- ICAM5 | c.524G>A p.R175Q | Missense Mutation (SNP) | VAF 10/66 reads (15%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.593); catalogued as rs760347968, COSV55748471; called by muse, mutect2, varscan2
- IL10RA | c.493C>T p.R165* | Nonsense Mutation (SNP) | VAF 13/71 reads (18%) | catalogued as rs1294929436, COSV104390273, COSV99923204; called by muse, mutect2, varscan2
- KCNA4 | c.774C>G p.F258L | Missense Mutation (SNP) | VAF 22/85 reads (26%) | SIFT deleterious (0); PolyPhen probably damaging (0.966); catalogued as COSV60254674; called by muse, mutect2, varscan2
- KLC3 | c.1386G>C p.K462N | Missense Mutation (SNP) | VAF 10/118 reads (8%) | SIFT deleterious (0); PolyPhen probably damaging (0.981); catalogued as COSV67266546; called by muse, mutect2
- KNL1 | c.5411G>T p.R1804I (on ENST00000346991 / NM_170589.5; = p.R1778I on NM_144508.5) | Missense Mutation (SNP) | VAF 6/46 reads (13%) | SIFT deleterious (0.02); PolyPhen benign (0.363); catalogued as COSV61158364; called by muse, mutect2, varscan2
- LAMC1 | c.1988G>C p.R663T | Missense Mutation (SNP) | VAF 11/53 reads (21%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.899); catalogued as COSV51159416, COSV99280346; called by muse, mutect2
- LDLRAD4 | c.544C>T p.P182S | Missense Mutation (SNP) | VAF 25/276 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV63340936; called by muse, mutect2
- MDGA1 | c.748C>G p.L250V | Missense Mutation (SNP) | VAF 46/128 reads (36%) | SIFT tolerated (0.34); PolyPhen benign (0.063); catalogued as COSV51799676; called by muse, varscan2
- NCOR2 | c.6184A>G p.T2062A | Missense Mutation (SNP) | VAF 4/26 reads (15%) | SIFT tolerated (0.24); PolyPhen benign (0.043); catalogued as COSV62301489; called by muse, mutect2
- NDUFB5 | c.26G>T p.R9L | Missense Mutation (SNP) | VAF 9/49 reads (18%) | SIFT deleterious (0); PolyPhen possibly damaging (0.777); catalogued as COSV52021255, COSV52021412; called by muse, mutect2, varscan2
- NEUROD4 | c.389G>C p.R130T | Missense Mutation (SNP) | VAF 17/86 reads (20%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV54472953; called by muse, mutect2, varscan2
- NFATC1 | c.371C>T p.S124L | Missense Mutation (SNP) | VAF 9/61 reads (15%) | SIFT deleterious (0.03); PolyPhen possibly damaging (0.466); catalogued as COSV53705561; called by muse, mutect2, varscan2
- NIPAL1 | c.447G>C p.L149F | Missense Mutation (SNP) | VAF 13/61 reads (21%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV55007325; called by muse, mutect2, varscan2
- NLGN4X | c.58A>T p.M20L | Missense Mutation (SNP) | VAF 28/42 reads (67%) | SIFT tolerated, low confidence (0.78); PolyPhen benign (0); catalogued as COSV52029360; called by muse, mutect2, varscan2
- NOTCH1 | c.6019G>A p.V2007M | Missense Mutation (SNP) | VAF 19/47 reads (40%) | SIFT deleterious (0); PolyPhen possibly damaging (0.806); catalogued as rs374168429, COSV99489427; called by muse, mutect2, varscan2
- NPY5R | c.401C>T p.S134L | Missense Mutation (SNP) | VAF 42/203 reads (21%) | SIFT tolerated (0.22); PolyPhen benign (0.021); catalogued as rs766307943, COSV58451575, COSV58453144; called by muse, mutect2, varscan2
- NTRK1 | c.1340A>T p.K447M | Missense Mutation (SNP) | VAF 38/202 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV62326934, COSV62327549; called by muse, mutect2, varscan2
- OR10S1 | c.371C>T p.T124I | Missense Mutation (SNP) | VAF 9/32 reads (28%) | SIFT deleterious (0.04); PolyPhen benign (0.022); catalogued as COSV73342934; called by muse, mutect2, varscan2
- OR14C36 | c.410G>C p.R137P | Missense Mutation (SNP) | VAF 14/124 reads (11%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.947); catalogued as COSV58602253, COSV58602467; called by muse, mutect2, varscan2
- OR52B2 | c.292G>A p.A98T | Missense Mutation (SNP) | VAF 19/92 reads (21%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.996); catalogued as COSV73209511; called by muse, mutect2, varscan2
- OTUD7A | c.1149G>C p.Q383H (on ENST00000307050 / NM_001382637.1; = p.Q376H on NM_130901.3) | Missense Mutation (SNP) | VAF 10/74 reads (14%) | SIFT tolerated (0.11); PolyPhen probably damaging (0.994); catalogued as COSV61041577; called by muse, mutect2, varscan2
- PARD6A | c.87C>A p.F29L | Missense Mutation (SNP) | VAF 21/92 reads (23%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.999); catalogued as COSV54668700, COSV54669318; called by muse, mutect2, varscan2
- PDE11A | c.184G>A p.A62T | Missense Mutation (SNP) | VAF 9/25 reads (36%) | SIFT tolerated (0.35); PolyPhen benign (0); catalogued as COSV53702992; called by muse, mutect2, varscan2
- PELI1 | c.712T>G p.L238V | Missense Mutation (SNP) | VAF 26/70 reads (37%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV62730599; called by muse, mutect2, varscan2
- PIGF | c.112G>C p.E38Q | Missense Mutation (SNP) | VAF 21/146 reads (14%) | SIFT tolerated (0.11); PolyPhen benign (0.16); catalogued as COSV53231988; called by muse, mutect2, varscan2
- PIP5K1A | c.34G>C p.V12L | Missense Mutation (SNP) | VAF 47/419 reads (11%) | SIFT tolerated, low confidence (0.3); PolyPhen benign (0.001); catalogued as COSV62959443; called by muse, mutect2, varscan2
- PLEKHG1 | c.1213C>T p.R405C | Missense Mutation (SNP) | VAF 15/46 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.993); catalogued as rs376799701; called by muse, mutect2, varscan2
- PLXNB3 | c.5209G>A p.E1737K | Missense Mutation (SNP) | VAF 7/120 reads (6%) | SIFT tolerated (0.08); PolyPhen possibly damaging (0.593); catalogued as rs1224327874, COSV62800347; called by muse, mutect2
- PLXND1 | c.1783G>A p.E595K | Missense Mutation (SNP) | VAF 25/129 reads (19%) | SIFT tolerated (0.07); PolyPhen benign (0.015); catalogued as rs747172721, COSV60717160; called by muse, mutect2, varscan2
- PNPLA3 | c.877G>C p.A293P | Missense Mutation (SNP) | VAF 10/40 reads (25%) | SIFT tolerated (0.2); PolyPhen benign (0.211); catalogued as COSV53378382, COSV53379813; called by muse, mutect2, varscan2
- PRMT5 | c.996C>G p.I332M | Missense Mutation (SNP) | VAF 6/66 reads (9%) | SIFT tolerated (0.14); PolyPhen possibly damaging (0.844); catalogued as COSV53547655; called by muse, mutect2, varscan2
- PRR27 | c.73G>A p.E25K | Missense Mutation (SNP) | VAF 4/70 reads (6%) | SIFT tolerated (0.25); PolyPhen benign (0.237); catalogued as COSV60640624; called by muse, mutect2
- PSG1 | c.435G>C p.E145D | Missense Mutation (SNP) | VAF 28/385 reads (7%) | SIFT deleterious (0.04); PolyPhen benign (0.005); catalogued as COSV54954385, COSV99739456; called by muse, mutect2
- RANBP3 | c.675T>A p.D225E | Missense Mutation (SNP) | VAF 21/51 reads (41%) | SIFT tolerated (0.51); PolyPhen benign (0.003); catalogued as COSV50380725, COSV50384073; called by muse, mutect2, varscan2
- REM1 | c.640G>A p.A214T | Missense Mutation (SNP) | VAF 12/20 reads (60%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV52429300; called by muse, mutect2, varscan2
- RETSAT | c.1682T>A p.L561H | Missense Mutation (SNP) | VAF 24/62 reads (39%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV55527518; called by muse, varscan2
- REXO1 | c.607C>A p.P203T | Missense Mutation (SNP) | VAF 5/31 reads (16%) | SIFT deleterious (0); PolyPhen possibly damaging (0.762); catalogued as COSV50084874; called by muse, mutect2
- RGS12 | c.1849C>T p.R617* | Nonsense Mutation (SNP) | VAF 28/141 reads (20%) | catalogued as rs747131973; called by muse, mutect2, varscan2
- RGS7 | c.1301C>T p.S434L | Missense Mutation (SNP) | VAF 24/132 reads (18%) | SIFT deleterious (0); PolyPhen probably damaging (1); catalogued as COSV58542235; called by muse, mutect2, varscan2
- SEC16B | c.1156G>A p.A386T | Missense Mutation (SNP) | VAF 9/121 reads (7%) | SIFT deleterious (0); PolyPhen probably damaging (0.987); catalogued as rs772191475, COSV57628551; called by muse, mutect2
- SGF29 | c.764G>A p.R255Q | Missense Mutation (SNP) | VAF 3/17 reads (18%) | SIFT tolerated (0.4); PolyPhen benign (0.014); catalogued as COSV57682179; called by muse, mutect2
- SH3GL1 | c.812C>T p.S271F | Missense Mutation (SNP) | VAF 17/75 reads (23%) | SIFT tolerated (0.13); PolyPhen benign (0.057); catalogued as rs778720794, COSV53658801; called by muse, mutect2, varscan2
- SLC38A2 | c.50G>A p.S17N | Missense Mutation (SNP) | VAF 34/166 reads (20%) | SIFT tolerated (0.3); PolyPhen probably damaging (0.986); catalogued as COSV56744159; called by muse, mutect2, varscan2
- SLC9B1 | c.496A>G p.I166V | Missense Mutation (SNP) | VAF 48/91 reads (53%) | SIFT tolerated (1); PolyPhen benign (0.015); catalogued as COSV56473455; called by muse, mutect2, varscan2
- SPART | c.770C>G p.S257C | Missense Mutation (SNP) | VAF 36/145 reads (25%) | SIFT deleterious (0.04); PolyPhen possibly damaging (0.723); catalogued as rs1232746924, COSV62087175; called by muse, mutect2, varscan2
- SPATA22 | c.508A>G p.K170E | Missense Mutation (SNP) | VAF 75/265 reads (28%) | SIFT tolerated (0.99); PolyPhen benign (0.059); catalogued as COSV52153752; called by muse, mutect2, varscan2
- SPTAN1 | c.6454G>A p.E2152K | Missense Mutation (SNP) | VAF 13/50 reads (26%) | SIFT tolerated (0.1); PolyPhen possibly damaging (0.903); catalogued as rs1273433822, COSV63988038; called by muse, mutect2, varscan2
- SVEP1 | c.9988A>G p.S3330G | Missense Mutation (SNP) | VAF 19/70 reads (27%) | SIFT tolerated (0.25); PolyPhen benign (0.185); catalogued as rs372409135; called by muse, mutect2, varscan2
- TDGF1 | c.361G>C p.D121H | Missense Mutation (SNP) | VAF 12/64 reads (19%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.934); catalogued as COSV56127795; called by muse, mutect2, varscan2
- TDRD6 | c.4942C>G p.Q1648E | Missense Mutation (SNP) | VAF 15/124 reads (12%) | SIFT tolerated (0.61); PolyPhen benign (0.003); catalogued as COSV60177313; called by muse, mutect2, varscan2
- TIE1 | c.1912C>A p.L638I | Missense Mutation (SNP) | VAF 26/58 reads (45%) | SIFT tolerated (0.4); PolyPhen benign (0.022); catalogued as COSV65250718; called by muse, mutect2, varscan2
- TNR | c.1711G>A p.E571K | Missense Mutation (SNP) | VAF 14/245 reads (6%) | SIFT tolerated (0.17); PolyPhen benign (0.334); catalogued as rs376305450; called by muse, mutect2
- TREM1 | c.47C>T p.S16L | Missense Mutation (SNP) | VAF 10/96 reads (10%) | SIFT tolerated (0.11); PolyPhen benign (0.144); catalogued as COSV55149253; called by muse, mutect2, varscan2
- TRPA1 | c.2605A>T p.T869S | Missense Mutation (SNP) | VAF 14/68 reads (21%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); catalogued as COSV51569369; called by muse, mutect2, varscan2
- TRPA1 | c.1793C>T p.T598M | Missense Mutation (SNP) | VAF 24/100 reads (24%) | SIFT tolerated (0.13); PolyPhen benign (0.054); catalogued as rs147715599; called by muse, mutect2, varscan2
- UBR4 | c.3547G>A p.E1183K | Missense Mutation (SNP) | VAF 49/100 reads (49%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.931); catalogued as COSV64395424; called by muse, mutect2, varscan2
- UGT8 | c.430G>A p.G144R | Missense Mutation (SNP) | VAF 51/154 reads (33%) | SIFT deleterious (0); PolyPhen probably damaging (0.916); catalogued as rs868025816, COSV60419669; called by muse, mutect2, varscan2
- UNC13A | c.1499T>C p.I500T | Missense Mutation (SNP) | VAF 40/128 reads (31%) | SIFT deleterious (0); PolyPhen possibly damaging (0.811); catalogued as COSV53204490; called by muse, mutect2, varscan2
- ZC3HC1 | c.389C>A p.P130Q | Missense Mutation (SNP) | VAF 33/166 reads (20%) | SIFT tolerated (0.26); PolyPhen probably damaging (0.965); catalogued as COSV61299535; called by muse, mutect2, varscan2
- ZMYND8 | c.1204G>C p.D402H (on ENST00000311275 / NM_001363741.2; = p.D422H on NM_012408.6 and 1 other RefSeq transcript) | Missense Mutation (SNP) | VAF 44/182 reads (24%) | SIFT deleterious, low confidence (0); PolyPhen probably damaging (0.999); catalogued as COSV53693451; called by muse, mutect2, varscan2
- ZNF107 | c.1685A>T p.N562I | Missense Mutation (SNP) | VAF 33/87 reads (38%) | SIFT tolerated (0.26); PolyPhen benign (0.034); catalogued as COSV61330671; called by muse, mutect2, varscan2
- ZNF35 | c.79G>A p.E27K | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT tolerated, low confidence (0.06); PolyPhen benign (0.041); catalogued as COSV56077127; called by muse, mutect2, varscan2
- ZNF451 | c.1958G>C p.R653P | Missense Mutation (SNP) | VAF 59/146 reads (40%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as COSV100674880, COSV62598991; called by muse, mutect2, varscan2
- ZNF804B | c.3268G>C p.E1090Q | Missense Mutation (SNP) | VAF 17/69 reads (25%) | SIFT deleterious (0); PolyPhen probably damaging (0.96); catalogued as COSV60842936; called by muse, mutect2, varscan2
- ZNHIT2 | c.1078G>A p.D360N | Missense Mutation (SNP) | VAF 14/79 reads (18%) | SIFT deleterious (0.02); PolyPhen benign (0.166); catalogued as COSV54205346; called by muse, mutect2, varscan2
- CCDC83 | c.311del p.K104Sfs*10 | Frame Shift Del (DEL) | VAF 18/97 reads (19%) | called by mutect2, pindel, varscan2
- CLCN3 | c.416C>A p.S139* | Nonsense Mutation (SNP) | VAF 12/76 reads (16%) | called by muse, mutect2
- DGKA | c.1101G>A p.R367= | Splice Region (SNP) | VAF 8/38 reads (21%) | called by muse, mutect2
- INPP4B | c.2535del p.D847Tfs*7 | Frame Shift Del (DEL) | VAF 22/79 reads (28%) | called by mutect2, pindel, varscan2
- MBD1 | c.723del p.I242Sfs*80 | Frame Shift Del (DEL) | VAF 8/60 reads (13%) | called by mutect2, pindel
- MTF2 | c.493G>A p.A165T | Missense Mutation (SNP) | VAF 16/54 reads (30%) | SIFT deleterious (0); PolyPhen possibly damaging (0.864); called by muse, mutect2
- PIGF | c.319G>C p.E107Q | Missense Mutation (SNP) | VAF 4/21 reads (19%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2
- PIWIL1 | c.1394G>A p.G465D | Missense Mutation (SNP) | VAF 10/120 reads (8%) | SIFT tolerated (0.21); PolyPhen benign (0.02); called by muse, mutect2
- PLEKHA8 | c.872C>G p.S291* | Nonsense Mutation (SNP) | VAF 23/99 reads (23%) | called by muse, mutect2, varscan2
- PLXNA2 | c.2611G>T p.E871* | Nonsense Mutation (SNP) | VAF 20/49 reads (41%) | called by muse, mutect2, varscan2
- PRAMEF18 | c.551A>T p.K184M | Missense Mutation (SNP) | VAF 126/884 reads (14%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.988); called by muse, mutect2, varscan2
- SYNE1 | c.21172C>T p.Q7058* (on ENST00000367255 / NM_182961.4; = p.Q6987* on NM_033071.3) | Nonsense Mutation (SNP) | VAF 18/155 reads (12%) | called by muse, mutect2, varscan2
- TP53 | c.826_833dup p.G279Pfs*69 | Frame Shift Ins (INS) | VAF 10/26 reads (38%) | called by mutect2, varscan2
- ZNF419 | c.1228G>T p.E410* | Nonsense Mutation (SNP) | VAF 25/148 reads (17%) | called by muse, mutect2, varscan2
- ZNHIT2 | c.889G>T p.E297* | Nonsense Mutation (SNP) | VAF 14/61 reads (23%) | called by muse, mutect2, varscan2
- CADPS2 | c.978G>A p.S326= | Silent (SNP) | VAF 16/88 reads (18%) | catalogued as rs772232660, COSV57348365; called by muse, mutect2, varscan2
- CAMTA1 | c.1938G>A p.T646= | Silent (SNP) | VAF 36/205 reads (18%) | catalogued as rs142993717, COSV57917025; called by muse, mutect2, varscan2
- CASP8AP2 | c.2001T>A p.T667= | Silent (SNP) | VAF 21/34 reads (62%) | called by muse, mutect2, varscan2
- COL5A1 | c.4308G>A p.P1436= | Silent (SNP) | VAF 5/17 reads (29%) | catalogued as rs200073020; ClinVar: benign; called by muse, mutect2, varscan2
- DCC | c.3348C>T p.I1116= | Silent (SNP) | VAF 11/40 reads (28%) | catalogued as rs1474376680, COSV71426219; called by muse, mutect2, varscan2
- FHL2 | c.609C>T p.R203= | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs745753003, COSV59080055; called by muse, mutect2, varscan2
- GRM2 | c.1254C>G p.L418= | Silent (SNP) | VAF 9/29 reads (31%) | catalogued as COSV56586369; called by muse, mutect2, varscan2
- KCNN2 | c.39G>A p.P13= (on ENST00000264773; = p.P225= on NM_021614.4) | Silent (SNP) | VAF 9/15 reads (60%) | catalogued as COSV53295087; called by muse, mutect2, varscan2
- KRT73 | c.63C>T p.S21= | Silent (SNP) | VAF 30/87 reads (34%) | catalogued as rs531582563, COSV59837710; called by muse, mutect2, varscan2
- MDGA1 | c.810C>A p.L270= | Silent (SNP) | VAF 22/64 reads (34%) | catalogued as COSV51799652; called by muse, varscan2
- NELFA | c.1137G>A p.A379= (on ENST00000542778; = p.A368= on NM_005663.5) | Silent (SNP) | VAF 4/18 reads (22%) | catalogued as rs762043976, COSV56394051; ClinVar: likely benign; called by muse, mutect2, varscan2
- OR2T3 | c.621C>T p.C207= | Silent (SNP) | VAF 298/455 reads (65%) | catalogued as rs1452493240, COSV62082480, COSV62083087; called by muse, mutect2, varscan2
- PALD1 | c.1971C>T p.F657= | Silent (SNP) | VAF 13/65 reads (20%) | catalogued as rs747434561, COSV54974344; called by muse, mutect2, varscan2
- PCDH11Y | c.2385C>T p.F795= (on ENST00000400457 / NM_032973.2; = p.F784= on NM_032971.3) | Silent (SNP) | VAF 11/193 reads (6%) | called by muse, mutect2
- PKD1L1 | c.2562A>G p.Q854= | Silent (SNP) | VAF 9/53 reads (17%) | catalogued as rs530943075, COSV56972996; called by muse, mutect2, varscan2
- PPIE | c.678C>G p.L226= | Silent (SNP) | VAF 19/97 reads (20%) | catalogued as rs754606907; called by muse, mutect2, varscan2
- PPP1R13L | c.1392G>A p.P464= | Silent (SNP) | VAF 14/110 reads (13%) | catalogued as rs767546785, COSV62908389; called by muse, mutect2, varscan2
- REXO4 | c.711C>T p.F237= | Silent (SNP) | VAF 14/43 reads (33%) | catalogued as rs201077059; called by muse, mutect2, varscan2
- TAF1L | c.1806C>T p.T602= | Silent (SNP) | VAF 57/185 reads (31%) | catalogued as COSV54259956, COSV54265989; called by muse, mutect2, varscan2
- TM7SF2 | c.696C>G p.L232= | Silent (SNP) | VAF 12/80 reads (15%) | catalogued as COSV54208794; called by muse, mutect2, varscan2
- YLPM1 | c.3975A>G p.E1325= | Silent (SNP) | VAF 19/88 reads (22%) | catalogued as rs778221363, COSV53117321; called by muse, mutect2, varscan2
- ZBTB22 | c.198G>A p.R66= | Silent (SNP) | VAF 50/122 reads (41%) | catalogued as COSV56471571; called by muse, mutect2, varscan2
- ZCCHC9 | c.93A>C p.G31= | Silent (SNP) | VAF 23/73 reads (32%) | catalogued as COSV54176810; called by muse, mutect2, varscan2
- GAD2 | c.-1G>T | 5'UTR (SNP) | VAF 12/30 reads (40%) | catalogued as rs766629595, COSV99392778, COSV99393847; called by muse, mutect2, varscan2
- NFATC3 | c.3107-5122C>T | Intron (SNP) | VAF 21/86 reads (24%) | catalogued as COSV100285739; called by muse, mutect2, varscan2
